CCDI case PBCGRK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2d4f0cca-e6a4-4d20-901d-43711cf5f25a

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.2 years (3,355 days).

Biospecimens (3 samples)
- Sample 0DV98L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV990: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DV99L: Tissue type: Tumor; Specimen type: Solid Tissue.
